Somatic mutation profile of tumor specimen TCGA-DJ-A4V5-01A (aliquot TCGA-DJ-A4V5-01A-11D-A257-08) from TCGA case TCGA-DJ-A4V5, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage IVA; Age at diagnosis: 55.1 years (20,108 days).
Specimen TCGA-DJ-A4V5-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7dacbd4b-d1c0-4890-9fd2-9d65018c8501.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DJ-A4V5-10A (Blood Derived Normal), aliquot TCGA-DJ-A4V5-10A-01D-A25A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5ab85e4e-4332-450b-8f9f-a28fb67d16e0

The open-access MAF lists 6 somatic variants for this specimen: 3 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 3, Silent 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CBWD1 | c.964A>G p.I322V | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.05); catalogued as rs1429288080; called by mutect2, varscan2
- DPP8 | c.2504A>C p.N835T (on ENST00000341861 / NM_001320875.2; = p.N719T on NM_017743.6) | Missense Mutation (SNP) | VAF 38/123 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55682448; called by muse, mutect2, varscan2
- WDR11 | c.141T>G p.D47E | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.967); catalogued as COSV54792223; called by muse, mutect2, varscan2
- GNAO1 | c.252C>T p.I84= | Silent (SNP) | VAF 12/57 reads (21%) | catalogued as rs756947463, COSV52614473; ClinVar: likely benign; called by muse, mutect2, varscan2
- POU2F3 | c.192C>T p.H64= | Silent (SNP) | VAF 61/218 reads (28%) | catalogued as COSV52797031; called by muse, mutect2, varscan2
- TBXA2R | c.153C>T p.G51= | Silent (SNP) | VAF 9/31 reads (29%) | catalogued as rs201810680, COSV64343874; called by muse, mutect2, varscan2
